Somatic mutation profile of tumor specimen 0DR53G from CCDI case PBCFGT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Synovial sarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of abdomen; Age at diagnosis: 13.6 years (4,955 days).
Specimen 0DR53G: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6dc8c4da-50fb-4dd4-a30b-0f454e606966.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DR535 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/330b8343-e563-475b-bcf6-2c4351a5f777

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 7, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGAP24 | c.1714C>T p.R572C (on ENST00000395184 / NM_001025616.3; = p.R479C on NM_031305.3) | Missense Mutation (SNP) | VAF 14/453 reads (3%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.926); catalogued as rs1176128263; called by muse, mutect2
- HSPG2 | c.7216G>A p.V2406M | Missense Mutation (SNP) | VAF 314/370 reads (85%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs1364243687, COSV65972242; called by muse, mutect2, varscan2
- SLITRK3 | c.935C>T p.S312L | Missense Mutation (SNP) | VAF 12/332 reads (4%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.95); catalogued as COSV53851729; called by muse, mutect2
- DSTYK | c.2690C>T p.P897L | Missense Mutation (SNP) | VAF 231/279 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FREM3 | c.3196G>T p.D1066Y | Missense Mutation (SNP) | VAF 35/514 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- OR2L5 | c.772T>G p.Y258D | Missense Mutation (SNP) | VAF 14/354 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- USP26 | c.2486T>C p.V829A | Missense Mutation (SNP) | VAF 11/316 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- NRBP2 | c.480G>A p.A160= | Silent (SNP) | VAF 163/386 reads (42%) | catalogued as rs1369993129; called by muse, varscan2
